Somatic mutation profile of tumor specimen 2115808b-6a0d-49bc-a8d7-b83bde (aliquot 2115808b-6a0d-49bc-a8d7-b83bde_D6_1) from CPTAC case 14OV011, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 2115808b-6a0d-49bc-a8d7-b83bde: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 688a519a-fe01-449d-ad2c-9f63567aedd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 554dab31-c7f5-4765-a1e3-9ceb94 (Blood Derived Normal), aliquot 554dab31-c7f5-4765-a1e3-9ceb94_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bda071d7-d0fa-4a9d-8e5d-45c06b7bb2cd

The open-access MAF lists 67 somatic variants for this specimen: 43 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 17, Intron 2, 5'UTR 1, 3'UTR 1, 3'Flank 1, 5'Flank 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 257/467 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEL | c.218G>A p.G73D (on ENST00000673714; = p.G70D on NM_001807.6) | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs767504446; called by muse, mutect2, varscan2
- GALNT18 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99925338; called by muse, mutect2, varscan2
- GRIA1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs531706550, COSV53596718; called by muse, mutect2, varscan2
- GRK4 | c.256G>T p.A86S (on ENST00000398052 / NM_182982.3; = p.A54S on NM_005307.3) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.39); catalogued as rs768758317; called by muse, mutect2, varscan2
- HSPG2 | c.12704G>A p.R4235Q | Missense Mutation (SNP) | VAF 127/921 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs780964669, COSV100760811; called by muse, mutect2, varscan2
- KLHL18 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as rs116903383; called by muse, mutect2, varscan2
- LPIN1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs754012602, COSV56768820; called by muse, mutect2, varscan2
- MSH2 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM1210410, COSV51885238; called by muse, mutect2, varscan2
- MUC16 | c.24794C>G p.S8265C | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); catalogued as rs745523804; called by muse, varscan2
- NRIP1 | c.690G>C p.M230I | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59658509; called by muse, mutect2, varscan2
- OR8I2 | c.879C>A p.N293K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs768585152; called by muse, mutect2, varscan2
- PCDHA3 | c.2091C>G p.N697K | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV63543751; called by muse, mutect2, varscan2
- STARD13 | c.3011T>C p.M1004T (on ENST00000336934 / NM_001243476.3; = p.M886T on NM_052851.3) | Missense Mutation (SNP) | VAF 59/418 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs947272183, COSV55231549; called by muse, mutect2, varscan2
- TMEM87B | c.91T>C p.C31R | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs1320120358; called by muse, mutect2, varscan2
- TRO | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs768861041; called by muse, mutect2, varscan2
- VPS13D | c.5534G>A p.R1845K | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1448514526; called by muse, mutect2, varscan2
- WDFY4 | c.1227C>G p.I409M | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as COSV57447976; called by muse, mutect2, varscan2
- WIZ | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344372987; called by muse, mutect2, varscan2
- ATP13A4 | c.2620T>G p.S874A | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CFAP61 | c.1652A>C p.Q551P | Missense Mutation (SNP) | VAF 133/445 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CORO2B | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DNAH11 | c.6746A>C p.K2249T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.6221C>T p.A2074V | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- GSPT2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- IKBKB | c.1997G>C p.R666P | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ITPRID2 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); called by muse, mutect2
- MAGEE1 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MCRS1 | c.1042G>C p.V348L | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- MEIOB | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, varscan2
- MUC16 | c.24643C>G p.H8215D | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, varscan2
- MUC16 | c.23984C>T p.S7995F | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- OR1S2 | c.697T>G p.C233G | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- OR2M7 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 29/646 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- OR9I1 | c.257C>G p.A86G | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PHIP | c.2546C>G p.S849C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- PKD1 | c.377C>G p.P126R | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- PPP6R2 | c.2429_2432del p.C810Sfs*34 (on ENST00000216061 / NM_001365836.1; = p.C776Sfs*34 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 88/256 reads (34%) | called by mutect2, varscan2
- RALBP1 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RALBP1 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRIM55 | c.1483G>C p.V495L | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF862 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGBL5 | c.69G>A p.E23= | Silent (SNP) | VAF 27/244 reads (11%) | catalogued as rs1346907038; called by muse, mutect2
- C10orf71 | c.3663G>A p.P1221= | Silent (SNP) | VAF 32/233 reads (14%) | catalogued as rs187004376, COSV60506997; called by muse, mutect2, varscan2
- C2orf69 | c.978C>T p.I326= | Silent (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- CCT8L2 | c.916C>T p.L306= | Silent (SNP) | VAF 152/522 reads (29%) | called by muse, mutect2, varscan2
- CEP290 | c.4035C>T p.I1345= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- CHST3 | c.504C>A p.I168= | Silent (SNP) | VAF 103/642 reads (16%) | catalogued as rs370284531; called by muse, mutect2, varscan2
- DPP9 | c.1917C>A p.T639= (on ENST00000598800; = p.T668= on NM_139159.5) | Silent (SNP) | VAF 87/142 reads (61%) | catalogued as COSV53593530; called by muse, mutect2, varscan2
- FAT2 | c.3423G>A p.V1141= | Silent (SNP) | VAF 115/247 reads (47%) | called by muse, mutect2, varscan2
- GARS1 | c.1242C>T p.Y414= | Silent (SNP) | VAF 72/428 reads (17%) | called by muse, mutect2, varscan2
- HSPA2 | c.1722C>T p.L574= | Silent (SNP) | VAF 15/222 reads (7%) | catalogued as rs779055791; called by muse, mutect2
- MAP3K5 | c.2469C>T p.F823= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs763688676; called by muse, mutect2, varscan2
- MUC16 | c.24243C>G p.S8081= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as rs1006727963; called by muse, mutect2, varscan2
- OLFML2B | c.1365C>T p.T455= | Silent (SNP) | VAF 56/350 reads (16%) | called by muse, mutect2, varscan2
- PRODH2 | c.1377C>T p.V459= (on ENST00000301175; = p.V383= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/366 reads (7%) | called by muse, mutect2
- SYT15 | c.328C>T p.L110= | Silent (SNP) | VAF 7/46 reads (15%) | called by mutect2, varscan2
- TBX4 | c.582G>A p.P194= | Silent (SNP) | VAF 60/398 reads (15%) | catalogued as rs370177908; called by muse, mutect2, varscan2
- TUBGCP3 | c.847C>T p.L283= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV56190622; called by muse, mutect2, varscan2
- BMS1P15 | n.640C>A | RNA (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65213945 C>G | 3'Flank (SNP) | VAF 52/333 reads (16%) | called by muse, mutect2, varscan2
- CYP7B1 | c.-97_-96dup | 5'UTR (INS) | VAF 28/66 reads (42%) | called by mutect2, varscan2
- DAO | chr12:108879849 C>G | 5'Flank (SNP) | VAF 68/430 reads (16%) | called by muse, mutect2, varscan2
- ITPA | c.189+26C>A | Intron (SNP) | VAF 48/504 reads (10%) | called by muse, mutect2
- KCTD7 | c.453+9A>C | Intron (SNP) | VAF 34/272 reads (13%) | called by muse, mutect2, varscan2
- MCMBP | c.*2G>T | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
